Somatic mutation profile of tumor specimen TCGA-6D-AA2E-01A (aliquot TCGA-6D-AA2E-01A-11D-A36X-10) from TCGA case TCGA-6D-AA2E, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 68.6 years (25,043 days).
Specimen TCGA-6D-AA2E-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) af596eea-1c9c-4155-8a87-47734d1344dd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-6D-AA2E-10A (Blood Derived Normal), aliquot TCGA-6D-AA2E-10A-01D-A370-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/574833af-fbd7-4ac8-8233-4dd373f698f4

The open-access MAF lists 28 somatic variants for this specimen: 19 protein-altering or splice-affecting, 7 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 7, Nonsense Mutation 2, Frame Shift Del 2, Intron 1, RNA 1, In Frame Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDAN1 | c.142G>T p.E48* | Nonsense Mutation (SNP) | VAF 14/50 reads (28%) | catalogued as COSV99141294; called by muse, mutect2, varscan2
- ELOA | c.1590A>G p.I530M | Missense Mutation (SNP) | VAF 6/112 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV101403663; called by muse, mutect2
- HNF4G | c.1124T>G p.L375R (on ENST00000354370 / NM_001330561.2; = p.L422R on NM_004133.5) | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.704); catalogued as COSV62965797, COSV62972949; called by muse, mutect2, varscan2
- LRP2 | c.3395A>G p.N1132S | Missense Mutation (SNP) | VAF 10/125 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99787588; called by muse, mutect2
- MACF1 | c.8506T>A p.S2836T | Missense Mutation (SNP) | VAF 32/116 reads (28%) | catalogued as rs776099458, COSV99243166; called by muse, mutect2, varscan2
- MECOM | c.494G>A p.C165Y (on ENST00000468789 / NM_001105078.4; = p.C353Y on NM_004991.4) | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99244457; called by muse, mutect2, varscan2
- NLRP1 | c.1457G>T p.R486M | Missense Mutation (SNP) | VAF 7/140 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99333582; called by muse, mutect2
- RD3 | c.419G>A p.R140H | Missense Mutation (SNP) | VAF 37/118 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.042); catalogued as COSV100879208; called by muse, mutect2, varscan2
- SCNN1D | c.164C>A p.S55* (on ENST00000338555; = p.S219* on NM_001130413.4) | Nonsense Mutation (SNP) | VAF 19/94 reads (20%) | catalogued as rs752340438, COSV100329727; called by muse, mutect2, varscan2
- SFPQ | c.1022C>A p.S341Y | Missense Mutation (SNP) | VAF 29/136 reads (21%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.977); catalogued as COSV100599374; called by muse, mutect2, varscan2
- SIRPA | c.487C>G p.Q163E | Missense Mutation (SNP) | VAF 24/119 reads (20%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs202077577, COSV100605115; called by muse, mutect2, varscan2
- SPEM2 | c.499A>G p.M167V | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100080937; called by muse, mutect2
- TACR3 | c.461G>A p.G154D | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100510318; called by muse, mutect2, varscan2
- ZFYVE26 | c.1601C>T p.S534L | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV100720284; called by muse, mutect2
- ZFYVE26 | c.1600T>A p.S534T | Missense Mutation (SNP) | VAF 7/75 reads (9%) | SIFT tolerated (0.59); PolyPhen benign (0.062); catalogued as COSV100720286; called by muse, mutect2
- SARS2 | c.590-5_590-2dup p.X197_splice | Splice Site (INS) | VAF 18/72 reads (25%) | called by mutect2, pindel, varscan2
- SPTBN2 | c.5154del p.S1719Pfs*11 | Frame Shift Del (DEL) | VAF 8/44 reads (18%) | called by mutect2, pindel, varscan2
- SUGP1 | c.668del p.L223Cfs*19 | Frame Shift Del (DEL) | VAF 15/79 reads (19%) | called by mutect2, pindel, varscan2
- ZNF624 | c.2461_2481del p.S821_L827del | In Frame Del (DEL) | VAF 22/169 reads (13%) | called by mutect2, pindel
- ATP7B | c.2958C>T p.S986= | Silent (SNP) | VAF 18/77 reads (23%) | catalogued as COSV54440467; called by muse, mutect2, varscan2
- C19orf54 | c.897G>A p.L299= | Silent (SNP) | VAF 18/82 reads (22%) | catalogued as COSV99648612; called by muse, mutect2, varscan2
- EGR2 | c.420C>G p.S140= | Silent (SNP) | VAF 27/148 reads (18%) | catalogued as COSV99654060; called by muse, mutect2, varscan2
- GAL3ST1 | c.756A>G p.Q252= | Silent (SNP) | VAF 4/33 reads (12%) | catalogued as rs986393706, COSV100143008; called by muse, mutect2, varscan2
- GPRC5B | c.54C>G p.L18= | Silent (SNP) | VAF 5/36 reads (14%) | catalogued as COSV100315027; called by muse, mutect2, varscan2
- HSPA8 | c.36C>T p.G12= | Silent (SNP) | VAF 11/47 reads (23%) | catalogued as rs536070549, COSV99914325; called by muse, mutect2, varscan2
- TBC1D8B | c.2022A>C p.G674= | Silent (SNP) | VAF 23/237 reads (10%) | catalogued as COSV99344176; called by muse, mutect2, varscan2
- DST | c.4297-4959A>G | Intron (SNP) | VAF 48/217 reads (22%) | catalogued as COSV55025785, COSV99754001; called by muse, mutect2, varscan2
- SSPOP | n.9432C>A | RNA (SNP) | VAF 6/76 reads (8%) | catalogued as COSV100947236; called by muse, mutect2
